Gene-level copy-number profile of tumor specimen TARGET-20-PARZUU-04A from TARGET case TARGET-20-PARZUU, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.0 years (3,273 days).
Specimen TARGET-20-PARZUU-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-AML.197e94b3-8405-5f25-954c-055659ec9905.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-20-PARZUU-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 367 have no estimate.
https://portal.gdc.cancer.gov/files/d7efb1c4-deb1-4cd5-81d4-c16f94ffa88a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 2,419; copy number 2: 57,708; copy number 3: 115.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–2): RSRP1.
- chr1:25,266,102–25,337,465, 4 genes: AL031432.2, RHD, SDHDP6, AL928711.1.
- chr11:5,776,165–5,783,355, 1 gene: OR52N5.
- chr14:106,425,359–106,473,000, 8 genes: IGHV7-40, AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1, IGHV3-42, IGHV3-43, IGHVII-43-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 32. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
